Surgical pathology report (de-identified scan), TCGA case TCGA-86-8280, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8280-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 6 x 5 x 2 cm Histologic type: Bronchiolo-alveolar adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

OpenClinica ID

[page 2 of 2]
Excision date	Laterali ty
	Left- lower

Source: NCI Genomic Data Commons file 38bfeebd-f246-488f-93c0-092f865193ad (TCGA-86-8280.49459CAE-EEE4-4E46-A8FC-EFBEB6CB1F5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).